Somatic mutation profile of tumor specimen BA2441D (aliquot aq-BA2441D) from BEATAML1.0 case 2250, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.4 years (18,398 days).
Specimen BA2441D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 095d8e4b-90a7-4888-89fe-878445b0308e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2267D (Solid Tissue Normal), aliquot aq-BA2267D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/745fc353-9b47-499f-9190-5e8934141192

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 3, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.3350C>A p.P1117H | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.213); catalogued as rs1442620290; called by muse, mutect2
- MXRA8 | c.679G>T p.A227S | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.94); catalogued as COSV100492100; called by muse, mutect2
- GPR162 | c.80C>A p.A27E | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- MROH7 | c.978C>A p.C326* | Nonsense Mutation (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- DIDO1 | c.4551G>T p.S1517= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV56623015; called by muse, mutect2
- FREM3 | c.1503G>T p.G501= | Silent (SNP) | VAF 5/97 reads (5%) | catalogued as rs1390060380; called by muse, mutect2
- MYD88 | c.21C>A p.G7= | Silent (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- CFL2 | chr14:34714615 C>A | 5'Flank (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
